Surgical pathology report (de-identified scan), TCGA case TCGA-3N-A9WB, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Greenville Health System, specimen TCGA-3N-A9WB-06A (Metastatic).

[page 1 of 3]
PATHOLOGY EXAMINATION

PATIENT NAME: [REDACTED]

COLLECTED: [REDACTED]

MED. REC. #: [REDACTED]

CLIENT: [REDACTED]

SOC. SEC. #: [REDACTED]

PHYSICIAN: [REDACTED]

GENDER: [REDACTED]

ADDITIONAL: [REDACTED]

ACCOUNT #: [REDACTED]

COPY TO/NOTES: [REDACTED]

SPECIMEN(S) RECEIVED:

A: Left flank melanoma excision

B: Left axillary nodule

CLINICAL DATA/HISTORY:

[REDACTED]

1C20-3
Melanoma NOS 8720/3
Site: L Flank C44.5
JAS 1/17/14

FINAL PATHOLOGIC DIAGNOSIS:

"LEFT FLANK MELANOMA", EXCISION: INVASIVE MALIGNANT MELANOMA.

- CLARK'S LEVEL: V.
- BRESLOW DEPTH: 1 CM.
- HOST RESPONSE: PRESENT.
- ULCERATION: PRIOR PROCEDURE SITE CHANGES NOTED.
- SATELLITE NODULES: PRESENT.
- TUMOR REGRESSION: NOT PRESENT.
- MITOTIC RATE: 6 MITOSES/mm²
- LYMPH-VASCULAR SPACE INVASION: PRESENT, MULTIPLE FOCI.
- PRE-EXISTING LESION: NONE IDENTIFIED.
- MARGIN: NEGATIVE.
- PATHOLOGIC STAGE (Based on AJCC/UICC TNM, 7th Ed.): pT4 N2c.
- ADDITIONAL FINDINGS: SEPARATE LENTIGINOUS COMPOUND DYSPLASTIC NEVUS WITH MODERATE ATYPIA; MARGINS CLEAR

B. "LEFT AXILLARY NODULE":

- METASTATIC MALIGNANT MELANOMA.
- SEE COMMENT.

COMMENT:

The frozen section diagnosis is confirmed. Regarding staging, definite lymph node tissue is not present in the part B "left axillary nodule" specimen, this is interpreted as an in-transit metastasis which, according to staging criteria is pN2c [REDACTED]. Clinical and surgical correlation are recommended.

ELECTRONICALLY SIGNED OUT

Board Certified in Dermatopathology

FROZEN SECTION DIAGNOSIS:

[REDACTED] MALIGNANT; CONSISTENT WITH METASTATIC MELANOMA.

Case discussed [REDACTED]

GROSS DESCRIPTION:

A. Left flank melanoma excision: The specimen is received fresh labeled, [REDACTED] left flank melanoma excision," and consists of an oriented excision of light tan skin and attached soft tissue measuring 22 x 6.5 x 1.8 cm. The specimen is oriented by three attached sutures. The specimen is inked as follows: 9 o'clock tip yellow, 10 to 12

[page 2 of 3]
to 3 o'clock blue, 3 to 6 to 8 o'clock green, deep margin black. Centrally on the skin is a bosselated faint purple area measuring 5 x 2.5 cm that lies 1.5 cm from both the 12 and 6 o'clock margins. The specimen is serially sectioned. One portion of the nodule lies within 0.2 cm of the deep margin. The remaining skin is grossly unremarkable. A representative section of the bosselated area is submitted for tissue banking. The specimen is serially sectioned and the bosselated area is entirely submitted. A1-A2) Central transverse 9:30-8:30 margins, sections contiguous. Orange ink designates adjacent tissue, not margin. A3-A4) Central transverse 10 and 8 o'clock margins, sections contiguous. Orange ink designates adjacent tissue, not margin (A3 mass at deepest infiltration grossly). A5-A6) Central transverse 10:30 and 7:30 margins, sections contiguous. Orange ink designates adjacent tissue, not margin. A7-A8) 11 and 7 o'clock margins, sections contiguous. Orange ink designates adjacent tissue, not margin. A9-A10) 11:30 and 6:30 margins, sections are contiguous. Orange ink designates adjacent tissue, not margin. A11-A12) 12 and 6 o'clock margins central transverse, sections are contiguous. Orange ink designates adjacent tissue, not margin. A13-A14) Central transverse 12:30 and 5:30 margins, sections contiguous. Orange ink designates adjacent tissue, not margin. A15-A16) Central transverse 1 and 5 o'clock margins, sections contiguous. Orange ink designates adjacent tissue, not margin. A17) Radial section of the 3 o'clock apex. A18) Radial section of the 9 o'clock apex. A grossing diagram is provided.

B. Left axillary nodule: The specimen is received fresh for frozen section evaluation, labeled "left axillary nodule", and consists of a single fragment of friable tan-brown tissue measuring 1.5 x 1.1 x 0.5 cm. The specimen is bisected revealing light tan, focally brown tissue. The specimen is entirely frozen in BFS1 cryoblock, frozen section remnant as B1 with touch preparations x1 obtained.

MICROSCOPIC DESCRIPTION:

A. Malignant melanoma is identified with multiple expansile nests of malignant cells extending into the subcutaneous tissue and displaying readily apparent mitoses numbering 6 mitoses/mm². Satellite nodules are apparent with separate foci of melanoma within the dermis and subcutaneous tissue away from the main mass. Areas of lymph vascular space invasion are identified. Prior biopsy site changes are noted. Malignant melanoma extends to within 4 mm. of the deep margin (slide A3) and to within 9 mm. of the medial (anterior) margin at 9:30 o'clock (superior, short stitch designated 12 o'clock during gross examination). A compound dysplastic nevus with moderate atypia is noted in slide A7. This not present at ink. Intravascular malignant melanoma extends to within 5 mm. of the 12 o'clock superior margin. Melanoma invades to a Clark's level of V and to a Breslow depth of 1 cm. Intralymphatic malignant melanoma extends to within 5 mm. of the 5:30 o'clock inferior margin.

B. Malignant melanoma is present involving adipose tissue. This extends to cauterized tissue edge. Definite lymph node tissue is not seen.

PROCEDURE/ADDENDUM: ADDENDUM

Date Entered:
Date Complete:
Date Reported:

ADDENDUM DIAGNOSIS:

ADDENDUM COMMENT:

Examination and selection of retrieved archived tissue for molecular analysis by [redacted]. Block A9 sent for BRAF mutation analysis on [redacted]. Test ordered by [redacted].
A9. See complete report attached.

[page 3 of 3]
SPECIMEN INFORMATION

SPECIMEN:

REQUISITION:

LAB REF NO:

COLLECTED:

REPORT STATUS Final

ORDERING PHYSICIAN

CLIENT INFORMATION

Test Name

Flexitest 1

In Range

Out of Range

Reference Range

Lab

Flexitest 1

Flexitest 1

Melanoma, BRAF V600 Mutation,

Specimen Source:

LEFT FLANK MELANOMA EXCISION

Block/Specimen ID:

BRAF V600 Mutation:

Not Detected

No mutation at codon 600 of BRAF was detected using a real-time PCR method

This FDA-cleared real-time PCR assay on the assesses for mutations at codon 600 of BRAF, particularly V600E, which are present in 40-60% of melanomas. Melanomas with codon 600 BRAF mutations are associated with response to the BRAF-directed kinase inhibitor vemurafenib

Tumor DNA is extracted from fixed tumor tissue and subjected to real-time PCR, with an approximate sensitivity of 5% mutation-bearing cells in a mixed sample. Other codon 600 BRAF mutations, beside the most common V600E (c.1799T>A) may not be detected by this method.

Performing Laboratory Information:

Page 1 - End of Report

BRAF Report pg 1 of 1

Source: NCI Genomic Data Commons file ba412cb2-9e9c-483f-b93a-4a6327959cf0 (TCGA-3N-A9WB.773FA4D0-E15C-4138-A961-4F610C1DE2AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).